Somatic mutation profile of tumor specimen 1105239 (aliquot 7316UP-2110-1105239) from CPTAC case C229764, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105239: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3801b99-0449-4fe9-a8c0-b35f835677fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105275 (Blood Derived Normal), aliquot 7316UP-1359-1105275; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0eddd94-448d-49c7-92f3-2e8c99bf1e94

The open-access MAF lists 4,454 somatic variants for this specimen: 2,608 protein-altering or splice-affecting, 1,237 silent, 609 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,301, Silent 1,237, Intron 306, Splice Site 129, Nonsense Mutation 100, 3'UTR 91, 5'UTR 73, RNA 67, Splice Region 64, 5'Flank 50, 3'Flank 22, Frame Shift Ins 11.

Variants (750 of 4,454; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6317G>A p.R2106H | Missense Mutation (SNP) | VAF 60/446 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520213, CM159385, COSV64678237; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ENG | c.1428+1G>A p.X476_splice | Splice Site (SNP) | VAF 97/641 reads (15%) | catalogued as rs863223542, CS111603; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HACE1 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 34/291 reads (12%) | catalogued as rs750371878, CM1510675; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSD3B7 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 145/1047 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894518, CM031220, COSV52680560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3656C>T p.T1219I | Missense Mutation (SNP) | VAF 105/447 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750949, CM020039, COSV52276093; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NBN | c.585-1G>A p.X195_splice | Splice Site (SNP) | VAF 25/197 reads (13%) | catalogued as rs1394578008; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PCNT | c.7126C>T p.Q2376* | Nonsense Mutation (SNP) | VAF 128/562 reads (23%) | catalogued as rs1555993038; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.402G>C p.M134I | Missense Mutation (SNP) | VAF 100/316 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1114167676, CM1211213, COSV64291845, COSV64293372, COSV64295066; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TUBB | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.146); catalogued as rs587777356, CM1212022; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs913551817; called by muse, mutect2
- ABCC2 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 134/465 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1224922647; called by muse, mutect2, varscan2
- ABCF3 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1295847995; called by muse, mutect2, varscan2
- ABCG5 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs758017120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAD10 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 74/367 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1274383922; called by muse, mutect2, varscan2
- ACAD8 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs772448494; called by muse, mutect2, varscan2
- ACE | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 49/353 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777339023, CM1514781; called by muse, mutect2, varscan2
- ACE | c.3125G>A p.G1042D | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV52006393; called by muse, mutect2, varscan2
- ACSBG1 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs1361410504; called by muse, mutect2, varscan2
- ACSL4 | c.1193C>T p.T398I (on ENST00000340800 / NM_022977.2; = p.T357I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as rs754071672; called by muse, mutect2, varscan2
- ACTN4 | c.399G>A p.E133= | Splice Region (SNP) | VAF 116/745 reads (16%) | catalogued as COSV53143186; called by muse, mutect2, varscan2
- ACTR6 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99498493; called by muse, mutect2
- ADAM17 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as rs1430253235; called by muse, mutect2, varscan2
- ADAM8 | c.639C>T p.F213= | Splice Region (SNP) | VAF 17/93 reads (18%) | catalogued as COSV69864711; called by muse, mutect2, varscan2
- ADAMTS10 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 78/565 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1555740508; called by muse, mutect2, varscan2
- ADGRA3 | c.2258C>T p.T753I | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs763701661; called by muse, mutect2, varscan2
- ADGRF3 | c.2242C>T p.L748F (on ENST00000311519 / NM_001145168.1; = p.L549F on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/442 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs753122177; called by muse, mutect2, varscan2
- ADGRF4 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 86/380 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs750563328; called by muse, mutect2, varscan2
- ADGRG1 | c.1952-1G>A p.X651_splice | Splice Site (SNP) | VAF 99/615 reads (16%) | catalogued as rs1207621709, COSV100342126; called by muse, mutect2, varscan2
- ADNP | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 48/250 reads (19%) | catalogued as COSV62427102; called by muse, mutect2, varscan2
- AFF2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60656822; called by muse, mutect2, varscan2
- AGBL2 | c.2699C>T p.T900I | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs1411813730; called by muse, mutect2, varscan2
- AGBL3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs1209924782; called by muse, varscan2
- AGFG2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 40/419 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53545737; called by muse, mutect2
- AGGF1 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1234035985; called by muse, mutect2, varscan2
- AGL | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54056390, COSV54059023; called by muse, mutect2, varscan2
- AGRN | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 91/409 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs4970342; called by muse, mutect2, varscan2
- AGRN | c.4826G>A p.G1609D | Missense Mutation (SNP) | VAF 101/376 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs777163307; called by muse, mutect2, varscan2
- AGTR2 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782129199; called by muse, mutect2, varscan2
- AHDC1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1279397466; called by muse, mutect2, varscan2
- AHNAK | c.16928C>T p.S5643F | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748428563; called by muse, mutect2, varscan2
- AHNAK | c.6784G>A p.E2262K | Missense Mutation (SNP) | VAF 24/694 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.279); catalogued as COSV99949312; called by muse, mutect2
- AHNAK2 | c.6307C>T p.P2103S | Missense Mutation (SNP) | VAF 102/604 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.372); catalogued as rs377027416; called by muse, varscan2
- AIFM1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs1200765574; called by muse, mutect2
- AKAP13 | c.5786C>T p.S1929L (on ENST00000394518 / NM_007200.5; = p.S1933L on NM_006738.6) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100774929; called by muse, mutect2, varscan2
- AKAP6 | c.5682G>A p.M1894I | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV55232007; called by muse, mutect2, varscan2
- AKAP9 | c.8293G>A p.A2765T (on ENST00000359028; = p.A2741T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs368001901, COSV62352435; called by muse, mutect2, varscan2
- AKT2 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 38/712 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100251360; called by muse, mutect2
- AL162417.1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1372730216; called by muse, mutect2, varscan2
- ALDH3A2 | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 53/480 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs761486859; called by muse, mutect2, varscan2
- ALG1 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 93/720 reads (13%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.527); catalogued as rs748774645; called by muse, mutect2, varscan2
- ALK | c.3856G>A p.G1286R | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66565679, COSV66592940; called by muse, mutect2, varscan2
- ALPK1 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs924008753; called by muse, mutect2, varscan2
- ALPK3 | c.2198G>A p.G733D | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs567079042; called by muse, mutect2, varscan2
- AMH | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 160/938 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs558432762; called by muse, varscan2
- ANKEF1 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765147617; called by muse, mutect2, varscan2
- ANKFN1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100593329; called by muse, mutect2, varscan2
- ANKIB1 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as rs982695434; called by muse, mutect2, varscan2
- ANKRD11 | c.6784G>A p.G2262S | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV56356097; called by muse, mutect2, varscan2
- ANKRD28 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1189778027; called by muse, mutect2, varscan2
- ANKRD30A | c.2648C>T p.A883V (on ENST00000611781; = p.A827V on NM_052997.2) | Missense Mutation (SNP) | VAF 46/345 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.827); catalogued as rs1466882372, COSV64606387; called by muse, mutect2, varscan2
- ANKRD34A | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1251816253, COSV60160428; called by muse, mutect2
- AOX1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV65984378; called by muse, mutect2, varscan2
- AOX1 | c.3453G>A p.W1151* | Nonsense Mutation (SNP) | VAF 29/203 reads (14%) | catalogued as rs76564086; called by muse, mutect2, varscan2
- AP000812.4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs541690359; called by muse, mutect2, varscan2
- APCDD1L | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 125/656 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as rs770754987; called by muse, mutect2, varscan2
- AQP12A | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1396148522; called by muse, mutect2
- ARAP3 | c.4402G>A p.G1468S | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.749); catalogued as COSV104381682; called by muse, mutect2, varscan2
- ARFGAP3 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1424089215; called by muse, mutect2, varscan2
- ARFGEF3 | c.4276C>T p.L1426F | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as rs372233023; called by muse, mutect2, varscan2
- ARHGAP18 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV63765793; called by muse, mutect2, varscan2
- ARHGAP31 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 28/548 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.589); catalogued as COSV51798020, COSV51798091, COSV99956673; called by muse, mutect2
- ARHGAP33 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 32/391 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.606); catalogued as rs201596534, COSV50130082; called by muse, mutect2
- ARHGEF11 | c.4253C>T p.A1418V | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as rs773257128; called by muse, mutect2, varscan2
- ARHGEF33 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.61); catalogued as rs1267599105; called by muse, mutect2, varscan2
- ARID2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57599034; called by muse, mutect2, varscan2
- ASAP2 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55634737; called by muse, mutect2, varscan2
- ASPM | c.8548G>A p.A2850T | Missense Mutation (SNP) | VAF 68/573 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.263); catalogued as rs201513235; called by muse, mutect2, varscan2
- ATAD2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761965716, COSV54881451; called by muse, mutect2, varscan2
- ATAD2B | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 8/132 reads (6%) | catalogued as rs1417847113, COSV53199587; called by muse, mutect2
- ATG13 | c.967G>A p.A323T (on ENST00000359513 / NM_001346321.1; = p.A286T on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.524); catalogued as rs745943231; called by muse, mutect2, varscan2
- ATP10B | c.3230G>A p.G1077D | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1414836377; called by muse, mutect2, varscan2
- ATP1A3 | c.3053-4C>T | Splice Region (SNP) | VAF 96/616 reads (16%) | catalogued as rs1555858732; called by muse, mutect2, varscan2
- ATP6V1B1 | c.50G>A p.C17Y | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs782793493; called by muse, varscan2
- ATP9B | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 84/539 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs755847576; called by muse, mutect2, varscan2
- ATXN2 | c.1981C>T p.P661S (on ENST00000550104; = p.P501S on NM_002973.4) | Missense Mutation (SNP) | VAF 85/419 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs1244280752; called by muse, mutect2, varscan2
- ATXN2L | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs573609543; called by muse, mutect2, varscan2
- ATXN7 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 28/704 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs922848988; called by muse, mutect2
- BAG6 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 139/615 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52991245, COSV52991701; called by muse, mutect2, varscan2
- BAHCC1 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.249); catalogued as rs782748795; called by muse, mutect2, varscan2
- BAIAP2L1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50056204, COSV99134141; called by muse, mutect2, varscan2
- BANK1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs186402440; called by muse, mutect2, varscan2
- BASP1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs752408964; called by muse, mutect2, varscan2
- BATF2 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 71/370 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100101835; called by muse, mutect2, varscan2
- BAZ2A | c.3574C>T p.P1192S | Missense Mutation (SNP) | VAF 112/638 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs772984421; called by muse, mutect2, varscan2
- BBS12 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.763); catalogued as rs1256863234; called by muse, mutect2
- BEGAIN | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs778462887, COSV100767048; called by muse, varscan2
- BEST1 | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 120/596 reads (20%) | catalogued as rs748921533, COSV56444501; called by muse, mutect2, varscan2
- BFSP1 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 69/584 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749440045; called by muse, mutect2, varscan2
- BMP6 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs149500097; called by muse, mutect2, varscan2
- BOC | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV56355064; called by muse, mutect2
- BOD1L1 | c.7006G>A p.E2336K | Missense Mutation (SNP) | VAF 74/319 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1379470066; called by muse, mutect2, varscan2
- BORCS6 | c.941G>A p.S314N | Missense Mutation (SNP) | VAF 28/755 reads (4%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); catalogued as rs1567561158; called by muse, mutect2
- BPIFB6 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1438140465; called by muse, mutect2, varscan2
- BRAF | c.1322C>T p.T441I (on ENST00000288602 / NM_001374244.1; = p.T401I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56074952, COSV56248932; called by muse, mutect2, varscan2
- BRAT1 | c.1846T>C p.F616L | Missense Mutation (SNP) | VAF 70/685 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs749767596; called by muse, mutect2, varscan2
- C10orf99 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100929357; called by muse, mutect2, varscan2
- C11orf80 | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1414202570; called by muse, mutect2, varscan2
- C15orf62 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 77/613 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs1201235872; called by muse, mutect2, varscan2
- C1R | c.337C>T p.P113S (on ENST00000536053 / NM_001354346.2; = p.P99S on NM_001733.7) | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as COSV56925642; called by muse, mutect2, varscan2
- C20orf96 | c.329C>T p.A110V (on ENST00000360321 / NM_153269.3; = p.A109V on NM_080571.1) | Missense Mutation (SNP) | VAF 89/419 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs952711137; called by muse, mutect2, varscan2
- C3 | c.3064G>A p.V1022I | Missense Mutation (SNP) | VAF 61/556 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as rs1322604877; called by muse, mutect2, varscan2
- C5 | c.4373G>A p.G1458E | Missense Mutation (SNP) | VAF 18/480 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV56332642; called by muse, mutect2
- C8B | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 72/576 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV64779104; called by muse, mutect2, varscan2
- CA8 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 98/524 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58772998; called by muse, mutect2, varscan2
- CACNA1E | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 21/479 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as COSV100702616; called by muse, mutect2
- CAMK2B | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs767063074; called by muse, mutect2, varscan2
- CAMTA2 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs773539959; called by muse, mutect2, varscan2
- CARD10 | c.1065+1G>A p.X355_splice | Splice Site (SNP) | VAF 22/88 reads (25%) | catalogued as rs1173215383; called by muse, mutect2
- CARMIL2 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1334240072; called by muse, mutect2, varscan2
- CARMIL2 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs1467907250; called by muse, mutect2, varscan2
- CASR | c.2119G>A p.A707T (on ENST00000490131; = p.A784T on NM_000388.4) | Missense Mutation (SNP) | VAF 135/682 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56136596; called by muse, mutect2, varscan2
- CBARP | c.1120G>A p.E374K (on ENST00000382477; = p.E354K on NM_152769.3) | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as rs1381906449, COSV53068523; called by muse, mutect2, varscan2
- CCDC14 | c.456G>A p.W152* (on ENST00000488653; = p.W104* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 36/246 reads (15%) | catalogued as rs373619932; called by muse, mutect2, varscan2
- CCDC154 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 66/384 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV66736592; called by muse, mutect2, varscan2
- CCDC58 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs1290347483; called by muse, mutect2, varscan2
- CCDC8 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 101/482 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.085); catalogued as rs1345376930; called by muse, mutect2, varscan2
- CCDC88C | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1455378745; called by muse, mutect2, varscan2
- CCDC9 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV55721171; called by muse, mutect2
- CCNQ | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs782235940; called by muse, varscan2
- CD163 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV63136157; called by muse, mutect2, varscan2
- CD1B | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 66/421 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs763137482; called by muse, mutect2, varscan2
- CD248 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 17/299 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.194); catalogued as COSV60937228; called by muse, mutect2
- CDC37L1 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.241); catalogued as COSV67866101; called by muse, mutect2, varscan2
- CDH18 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as rs1280042011; called by muse, mutect2, varscan2
- CDH19 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as COSV50984428; called by muse, mutect2, varscan2
- CDHR3 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs756786579; called by mutect2, varscan2
- CDK11B | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1462668002; called by muse, mutect2, varscan2
- CDK12 | c.3425C>T p.S1142F | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV70999811; called by muse, mutect2
- CDK18 | c.1013C>T p.P338L (on ENST00000506784 / NM_212503.3; = p.P308L on NM_002596.4) | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1241235480; called by muse, mutect2, varscan2
- CDSN | c.887A>G p.Y296C | Missense Mutation (SNP) | VAF 117/588 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs758844723, COSV99457284; called by muse, mutect2, varscan2
- CEBPA | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57197994; called by muse, varscan2
- CEP112 | c.2864+8C>T | Splice Region (SNP) | VAF 21/139 reads (15%) | catalogued as COSV100439630; called by muse, mutect2, varscan2
- CEP290 | c.3928G>A p.E1310K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV100468190; called by muse, mutect2
- CEP290 | c.3314C>T p.T1105I | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565853251; called by muse, mutect2
- CES4A | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58658204; called by muse, mutect2, varscan2
- CFAP44 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs780990198, COSV55610851; called by muse, mutect2, varscan2
- CFAP54 | c.6856G>A p.V2286M | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1156630217, COSV61570477; called by muse, mutect2
- CH25H | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 24/469 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV64092286; called by muse, mutect2
- CHAC1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 102/443 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.055); catalogued as rs1194596095; called by muse, mutect2, varscan2
- CHADL | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1159322609; called by muse, mutect2, varscan2
- CHD1L | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1553973253; called by muse, mutect2, varscan2
- CHIA | c.985C>T p.Q329* (on ENST00000343320; = p.Q221* on NM_021797.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/250 reads (14%) | catalogued as COSV58474271; called by muse, mutect2, varscan2
- CHST14 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs376435449; called by muse, mutect2, varscan2
- CIC | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50546678; called by muse, mutect2, varscan2
- CILP2 | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs772983515; called by muse, mutect2, varscan2
- CKB | c.349-1G>A p.X117_splice | Splice Site (SNP) | VAF 72/378 reads (19%) | catalogued as rs1468777836; called by muse, varscan2
- CLEC4F | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55478925; called by muse, mutect2, varscan2
- CLPTM1L | c.162+1G>A p.X54_splice | Splice Site (SNP) | VAF 29/153 reads (19%) | catalogued as rs374542300; called by muse, mutect2, varscan2
- CLSTN1 | c.1871C>T p.T624I (on ENST00000377298 / NM_001009566.3; = p.T614I on NM_014944.4) | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV63646552; called by muse, mutect2, varscan2
- CMA1 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753673742; called by muse, mutect2
- CMKLR1 | c.133G>A p.V45M (on ENST00000312143 / NM_001142344.2; = p.V43M on NM_004072.3) | Missense Mutation (SNP) | VAF 74/409 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs779039224; called by muse, mutect2, varscan2
- CNGB3 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 94/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1386894445, COSV100182795; called by muse, mutect2, varscan2
- CNOT4 | c.1349G>A p.G450D (on ENST00000315544 / NM_001190848.1; = p.G447D on NM_013316.4) | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as rs913822014; called by muse, mutect2, varscan2
- CNPPD1 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs968254835; called by muse, mutect2, varscan2
- CNR1 | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs757730631, COSV100759262; called by muse, mutect2, varscan2
- COBLL1 | c.2909C>T p.P970L (on ENST00000392717; = p.P932L on NM_014900.5) | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as rs1558925506; called by muse, mutect2
- COG2 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as rs774526575; called by muse, mutect2, varscan2
- COL4A1 | c.2758C>T p.P920S | Missense Mutation (SNP) | VAF 122/588 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs142828583; called by muse, mutect2, varscan2
- COL4A3 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 23/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67416146; called by muse, mutect2
- COL4A5 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM085960; called by muse, mutect2, varscan2
- COL4A6 | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV57875408; called by muse, mutect2, varscan2
- COL5A1 | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 98/754 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs863223447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs1260436274; called by muse, mutect2, varscan2
- COL7A1 | c.8226+1G>A p.X2742_splice | Splice Site (SNP) | VAF 48/161 reads (30%) | catalogued as CD095172; called by muse, mutect2, varscan2
- COL7A1 | c.7521+1G>A p.X2507_splice | Splice Site (SNP) | VAF 37/175 reads (21%) | catalogued as rs1560200657; called by muse, mutect2, varscan2
- COL7A1 | c.3956C>T p.P1319L | Missense Mutation (SNP) | VAF 32/586 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as COSV60397971; called by muse, mutect2
- COL9A1 | c.1948C>T p.L650F | Missense Mutation (SNP) | VAF 30/656 reads (5%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.565); catalogued as rs1269618884, COSV57884268; called by muse, mutect2
- COMMD8 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV101055766; called by muse, mutect2, varscan2
- CORO1C | c.855G>A p.K285= | Splice Region (SNP) | VAF 26/100 reads (26%) | catalogued as rs1185037194; called by muse, mutect2, varscan2
- CORO2B | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV55951975; called by muse, mutect2
- CPLANE2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as rs868709955; called by muse, mutect2, varscan2
- CPNE7 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as rs775569816; called by muse, mutect2, varscan2
- CPSF2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.817); catalogued as COSV54099328; called by muse, mutect2, varscan2
- CRACR2A | c.1602+1G>A p.X534_splice | Splice Site (SNP) | VAF 17/79 reads (22%) | catalogued as rs1395377766; called by muse, mutect2, varscan2
- CRB1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66332235, COSV66332501; called by muse, mutect2, varscan2
- CREBBP | c.4606G>A p.E1536K | Missense Mutation (SNP) | VAF 22/525 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1567269379; called by muse, mutect2
- CROCC | c.4499C>T p.P1500L | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs748575001; called by muse, mutect2, varscan2
- CRYGC | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 97/504 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs544008612, COSV52204963; called by muse, mutect2, varscan2
- CRYZ | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs765762437; called by muse, mutect2, varscan2
- CSMD3 | c.2869C>T p.L957F (on ENST00000297405 / NM_001363185.1; = p.L853F on NM_052900.3) | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.999); catalogued as COSV52157753, COSV99824998, COSV99836689; called by muse, mutect2, varscan2
- CSNK1A1L | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 104/487 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.328); catalogued as rs368855406; called by muse, mutect2, varscan2
- CUL2 | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66079599; called by muse, mutect2, varscan2
- CXorf66 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100983826, COSV100983949; called by muse, mutect2
- CYLC1 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as COSV61412049; called by muse, mutect2, varscan2
- CYP11A1 | c.1434+1G>A p.X478_splice | Splice Site (SNP) | VAF 76/540 reads (14%) | catalogued as COSV99166283; called by muse, mutect2, varscan2
- CYP2R1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58127639; called by muse, mutect2, varscan2
- CYP46A1 | c.696C>T p.F232= | Splice Region (SNP) | VAF 27/228 reads (12%) | catalogued as rs1350698478, COSV55894570; called by muse, mutect2, varscan2
- DACH1 | c.1891G>A p.V631I (on ENST00000619232 / NM_001366712.1; = p.V377I on NM_004392.6) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57522030; called by muse, mutect2, varscan2
- DACT1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 84/589 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.099); catalogued as rs1369377514; called by muse, mutect2, varscan2
- DACT2 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1198336544; called by muse, mutect2, varscan2
- DAOA | c.44+1G>A p.X15_splice | Splice Site (SNP) | VAF 23/183 reads (13%) | catalogued as COSV100298899; called by muse, mutect2, varscan2
- DCN | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV50007851, COSV99271940; called by muse, mutect2, varscan2
- DDC | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 62/676 reads (9%) | catalogued as rs1306265578; called by muse, mutect2
- DDX11 | c.2212G>A p.E738K (on ENST00000545668 / NM_152438.2; = p.E688K on NM_004399.3) | Missense Mutation (SNP) | VAF 114/546 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446735610; called by muse, mutect2, varscan2
- DDX59 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58752814; called by muse, mutect2, varscan2
- DEF6 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 88/534 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV57355046; called by muse, mutect2, varscan2
- DENND1C | c.1295G>A p.G432D | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1231986466, COSV57568682; called by muse, mutect2, varscan2
- DENND5A | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs1046003065; called by muse, mutect2
- DGAT1 | c.198G>A p.L66= | Splice Region (SNP) | VAF 19/99 reads (19%) | catalogued as COSV59782313; called by muse, mutect2, varscan2
- DGKA | c.708C>T p.N236= | Splice Region (SNP) | VAF 22/145 reads (15%) | catalogued as rs758503630; called by muse, mutect2, varscan2
- DHX33 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56580191; called by muse, mutect2, varscan2
- DICER1 | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV58628722; called by muse, mutect2, varscan2
- DIP2C | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as COSV55156216; called by muse, mutect2, varscan2
- DIPK1B | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.065); catalogued as rs893780766; called by muse, mutect2, varscan2
- DMRTC2 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99523294; called by muse, mutect2, varscan2
- DMXL2 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV51842376; called by muse, mutect2, varscan2
- DNAH3 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54503305; called by muse, varscan2
- DNAH6 | c.7877G>A p.G2626E | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.566); catalogued as COSV52881594; called by muse, mutect2, varscan2
- DNAH9 | c.9246+1G>A p.X3082_splice | Splice Site (SNP) | VAF 19/100 reads (19%) | catalogued as rs1367118833; called by muse, mutect2, varscan2
- DNAJB6 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1563137106; called by muse, mutect2, varscan2
- DNAJC5B | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 85/428 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52535665; called by muse, mutect2, varscan2
- DNASE2B | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 32/213 reads (15%) | catalogued as rs199881802; called by muse, mutect2, varscan2
- DNHD1 | c.6053C>T p.T2018I | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1287613931; called by muse, varscan2
- DNHD1 | c.6059C>T p.T2020I | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs1057495175; called by muse, varscan2
- DNHD1 | c.11632C>T p.P3878S | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1232660118; called by muse, mutect2
- DNM2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 83/556 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as COSV58965232; called by muse, varscan2
- DNM2 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 58/550 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1294472636; called by muse, varscan2
- DOCK4 | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV101447909; called by muse, mutect2, varscan2
- DOCK5 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.56); catalogued as COSV52415407; called by muse, mutect2
- DOCK8 | c.6109G>A p.A2037T | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs866262584; called by muse, mutect2, varscan2
- DOCK9 | c.717+1G>A p.X239_splice (on ENST00000376460 / NM_001366676.2; = p.X240_splice on NM_015296.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as rs1471264753; called by muse, mutect2, varscan2
- DOT1L | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV67110732; called by muse, mutect2, varscan2
- DPYSL3 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV58330111; called by muse, mutect2
- DPYSL3 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV100575106; called by muse, mutect2
- DSG2 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 46/403 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1156468696, COSV55197790; called by muse, mutect2, varscan2
- DTNB | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1319648676; called by muse, varscan2
- DUSP2 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 73/379 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.567); catalogued as rs1242351072; called by muse, mutect2, varscan2
- DVL1 | c.1610G>A p.G537D (on ENST00000378888 / NM_001330311.2; = p.G512D on NM_004421.3) | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.361); catalogued as rs760842641; called by muse, mutect2, varscan2
- DYNC1LI1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1411141475; called by muse, mutect2, varscan2
- E2F8 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as COSV51461857; called by muse, mutect2, varscan2
- EFCAB11 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.551); catalogued as COSV99965636; called by muse, mutect2
- EFCAB8 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV68700997; called by muse, mutect2
- EFEMP1 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 22/532 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV62616577; called by muse, mutect2
- EFHB | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 79/383 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.396); catalogued as COSV55547870; called by muse, mutect2, varscan2
- EFR3B | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV53120125; called by muse, mutect2, varscan2
- EIF2AK1 | c.550-8C>T | Splice Region (SNP) | VAF 12/88 reads (14%) | catalogued as rs1164772522; called by muse, mutect2
- EIF2AK4 | c.3652G>A p.D1218N | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1280353793; called by muse, mutect2, varscan2
- EIF4B | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV50404621; called by muse, mutect2, varscan2
- ELF4 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.88); catalogued as rs1364932790, COSV57453146; called by muse, mutect2
- ELFN1 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774563944, COSV70035105; called by muse, mutect2, varscan2
- ELN | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 108/587 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs1216302521; called by muse, mutect2, varscan2
- EPB41L4A | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.341); catalogued as rs967013893; called by muse, mutect2, varscan2
- EPHA1 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs770297450; called by muse, mutect2, varscan2
- EPHA10 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57624618; called by muse, mutect2, varscan2
- EPHA5 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV56664667; called by muse, mutect2
- EPHB4 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs920850385; called by muse, mutect2, varscan2
- ERGIC1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs763595862; called by muse, mutect2, varscan2
- ERVV-2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 104/609 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.649); catalogued as rs1158398547; called by muse, mutect2, varscan2
- ESR1 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 102/569 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.041); catalogued as rs201118302, COSV52783458; called by muse, mutect2, varscan2
- ESYT1 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 90/531 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.021); catalogued as COSV99919670; called by muse, mutect2, varscan2
- EXPH5 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV56198909; called by muse, mutect2, varscan2
- EYA2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs753782099; called by muse, mutect2, varscan2
- EYA4 | c.581-1G>A p.X194_splice | Splice Site (SNP) | VAF 20/512 reads (4%) | catalogued as COSV100765069, COSV62058516; called by muse, mutect2
- EZHIP | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 99/218 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as rs372074283; called by muse, mutect2, varscan2
- FAM110A | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1213567847; called by muse, mutect2
- FAM160A2 | c.1481C>A p.P494H (on ENST00000449352 / NM_001098794.2; = p.P508H on NM_032127.4) | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56412305; called by muse, mutect2
- FAM71D | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1047418715; called by muse, mutect2
- FAM71E2 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 70/764 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs989423626; called by muse, mutect2
- FANCA | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 114/489 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs148419748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCF | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 68/716 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs149687560; called by muse, mutect2
- FASTK | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 38/439 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as rs1473315811; called by muse, mutect2
- FAT2 | c.8609C>T p.T2870I | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs765925343; called by muse, mutect2, varscan2
- FAT2 | c.6805C>T p.P2269S | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs764158288, COSV55815572; called by muse, mutect2, varscan2
- FAT4 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1193758539; called by muse, mutect2, varscan2
- FBXO11 | c.290G>A p.S97N (on ENST00000403359 / NM_001190274.2; = p.S13N on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as rs777106251; called by muse, mutect2, varscan2
- FBXO31 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100291595; called by muse, mutect2, varscan2
- FBXO33 | c.704T>A p.I235N | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV53233270; called by mutect2, varscan2
- FBXO40 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs986296977, COSV100573301; called by muse, mutect2, varscan2
- FCRL3 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.409); catalogued as COSV100943376; called by muse, mutect2, varscan2
- FER1L5 | c.1981G>A p.A661T (on ENST00000623019; = p.A666T on NM_001293083.2) | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV101330844; called by muse, mutect2, varscan2
- FGFBP1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV52586857; called by muse, mutect2, varscan2
- FH | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM020706; called by muse, mutect2
- FIGNL1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100794969; called by muse, mutect2, varscan2
- FILIP1 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); catalogued as COSV52723403; called by muse, mutect2
- FKBP6 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 27/626 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs374791338, COSV52720273, COSV52721341; called by muse, mutect2
- FLNC | c.4963G>A p.G1655S | Missense Mutation (SNP) | VAF 127/758 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV57958685; called by muse, mutect2, varscan2
- FMNL2 | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV99979087; called by muse, mutect2, varscan2
- FMOD | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs752935066; called by muse, mutect2, varscan2
- FNBP4 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1354729274; called by muse, mutect2
- FOLH1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57052446; called by muse, mutect2, varscan2
- FOXRED2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs577110470; called by muse, mutect2, varscan2
- FPGS | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100785278; called by muse, mutect2, varscan2
- FSHR | c.2003G>A p.R668K | Missense Mutation (SNP) | VAF 71/386 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1182666505, COSV100438348; called by muse, mutect2, varscan2
- FST | c.278-1G>A p.X93_splice | Splice Site (SNP) | VAF 49/214 reads (23%) | catalogued as COSV99887221; called by muse, mutect2
- GAB2 | c.1514G>A p.G505E (on ENST00000361507 / NM_080491.3; = p.G467E on NM_012296.3) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs754602778, COSV60870712, COSV60871071; called by mutect2, varscan2
- GABRP | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54662872; called by muse, mutect2, varscan2
- GAD1 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 46/429 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV60152516; called by muse, mutect2, varscan2
- GAK | c.3272C>T p.S1091F | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs757416130; called by mutect2, varscan2
- GALNT10 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs1205250896; called by muse, mutect2, varscan2
- GALNT14 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140948320; called by muse, mutect2, varscan2
- GAS2L3 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs1452071194; called by muse, mutect2, varscan2
- GATA1 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as CS063314, COSV64961387, COSV64961668; called by muse, mutect2, varscan2
- GATA3 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 30/475 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60522624; called by muse, mutect2
- GATB | c.1331G>A p.S444N | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as rs761753310; called by muse, mutect2, varscan2
- GBP2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65069911; called by muse, mutect2, varscan2
- GCFC2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58079561; called by muse, mutect2
- GFOD1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV64955144; called by muse, mutect2, varscan2
- GFPT2 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.219); catalogued as rs747062916; called by muse, mutect2, varscan2
- GGA2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs865953469; called by muse, mutect2
- GIGYF1 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as rs1262173546; called by muse, mutect2, varscan2
- GIGYF2 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65247299; called by muse, mutect2, varscan2
- GIMAP4 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.058); catalogued as rs909825003, COSV55431136; called by muse, mutect2, varscan2
- GLB1L2 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1442946444, COSV60279138; called by muse, mutect2, varscan2
- GLI2 | c.3275G>A p.R1092K (on ENST00000361492 / NM_001374353.1; = p.R1109K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/822 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as COSV100082269; called by muse, mutect2
- GLI3 | c.1466G>A p.R489K | Missense Mutation (SNP) | VAF 89/576 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs757946644; called by muse, varscan2
- GLYATL3 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1366139244; called by muse, mutect2, varscan2
- GOLGA1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs1051814800; called by muse, mutect2
- GP1BB | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 211/792 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs1237023924; called by muse, mutect2, varscan2
- GPATCH1 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs769103928; called by muse, varscan2
- GPATCH8 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV59194383; called by muse, mutect2, varscan2
- GPC6 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as COSV65526064; called by muse, mutect2, varscan2
- GPN1 | c.350+1G>A p.X117_splice | Splice Site (SNP) | VAF 12/77 reads (16%) | catalogued as rs1558486167; called by muse, mutect2, varscan2
- GPN3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1208040516, COSV99959985; called by muse, mutect2, varscan2
- GPR146 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV99866339; called by muse, mutect2, varscan2
- GPR179 | c.3854G>A p.G1285D (on ENST00000621958; = p.G1284D on NM_001004334.4) | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1349066788; called by muse, mutect2, varscan2
- GPR25 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 146/476 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1470587407, COSV100421750; called by muse, varscan2
- GPR85 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51783474, COSV51785882; called by muse, mutect2, varscan2
- GPRC6A | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372617351, COSV59953010; called by muse, mutect2, varscan2
- GRIN2D | c.3479G>A p.G1160D | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as rs1422044339; called by muse, mutect2, varscan2
- GRK7 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 77/592 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99380238; called by muse, mutect2, varscan2
- GSAP | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 17/382 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as COSV57529822; called by muse, mutect2
- GSG1L | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1276878770; called by muse, mutect2, varscan2
- GTPBP3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs369410374; called by muse, mutect2, varscan2
- GUCY2C | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as rs1159423242; called by muse, mutect2, varscan2
- H3C7 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 84/381 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV55099645; called by muse, mutect2, varscan2
- HBEGF | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 79/330 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.293); catalogued as COSV50183609; called by muse, mutect2, varscan2
- HDC | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 32/794 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as rs1259413173; called by muse, mutect2
- HEATR3 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 101/484 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867437937; called by muse, mutect2, varscan2
- HEATR5B | c.4613G>A p.W1538* | Nonsense Mutation (SNP) | VAF 55/384 reads (14%) | catalogued as rs1347152120; called by muse, mutect2, varscan2
- HECTD4 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV101106946; called by muse, mutect2, varscan2
- HEMGN | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV52326197; called by muse, mutect2, varscan2
- HERC2 | c.7111C>T p.P2371S | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as rs776189974; called by muse, mutect2, varscan2
- HHIPL2 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 72/570 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV58565064; called by muse, varscan2
- HIPK4 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52519235; called by muse, mutect2, varscan2
- HIVEP1 | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs964651822; called by muse, mutect2, varscan2
- HIVEP2 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1221838320, COSV50008408; called by muse, mutect2, varscan2
- HLA-DQA2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 118/744 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs755273163; called by muse, varscan2
- HMGCLL1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs749751733; called by muse, mutect2, varscan2
- HOXA9 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as rs1412102757; called by muse, mutect2, varscan2
- HOXB3 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.354); catalogued as rs964014129; called by muse, mutect2, varscan2
- HPS1 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 108/364 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57269241; called by muse, mutect2, varscan2
- HSD11B2 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 32/940 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs913489956; called by muse, mutect2
- HSF1 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.055); catalogued as rs1280144245; called by muse, mutect2, varscan2
- HSP90AA1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs761020264; called by muse, mutect2, varscan2
- HTRA2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as COSV51206238; called by muse, mutect2, varscan2
- HUWE1 | c.4187C>T p.P1396L | Missense Mutation (SNP) | VAF 23/269 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1556977725; called by muse, mutect2
- HYOU1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101345606; called by muse, mutect2, varscan2
- IDH3G | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs782671638, COSV54207621; called by muse, mutect2, varscan2
- IFNL2 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV59593857, COSV59593993; called by muse, mutect2, varscan2
- IFT88 | c.425+1G>A p.X142_splice (on ENST00000319980 / NM_001318493.2; = p.X133_splice on NM_006531.5 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 32/146 reads (22%) | catalogued as rs948410524; called by muse, mutect2, varscan2
- IGLL1 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.459); catalogued as rs766536756; called by muse, mutect2, varscan2
- IGSF1 | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV63838003; called by muse, mutect2
- IGSF9B | c.3145G>A p.G1049R | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs1403149188, COSV58068118; called by muse, mutect2
- IKBKB | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 66/310 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV60600216; called by muse, mutect2, varscan2
- IL18RAP | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826052, COSV51828701; called by muse, mutect2, varscan2
- IL27 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100112566; called by muse, mutect2, varscan2
- IL36B | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs779061101; called by muse, mutect2, varscan2
- IL4I1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 52/374 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1012762903; called by muse, mutect2, varscan2
- INHBE | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as rs1214664886; called by muse, mutect2, varscan2
- INSIG1 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs897710551; called by muse, mutect2, varscan2
- IQCA1 | c.1921dup p.T641Nfs*14 | Frame Shift Ins (INS) | VAF 19/152 reads (13%) | catalogued as rs1559363996; called by mutect2, pindel, varscan2
- IRF2BP2 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.302); catalogued as rs1385363381; called by muse, mutect2, varscan2
- ITFG2 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957915; called by muse, mutect2, varscan2
- ITGA1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99251491; called by muse, mutect2, varscan2
- ITGA3 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 22/437 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.46); catalogued as rs972830593; called by muse, mutect2
- ITIH2 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs148172382; called by muse, mutect2, varscan2
- ITIH6 | c.3644G>A p.R1215K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.096); catalogued as COSV54492293; called by muse, mutect2
- JAG1 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 63/509 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1275874823; called by muse, mutect2, varscan2
- JMJD6 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs1408853901; called by muse, mutect2
- JMJD7-PLA2G4B | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV59827402, COSV59828667; called by muse, mutect2, varscan2
- JSRP1 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 86/981 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs376493961; called by muse, mutect2
- KANK2 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV62007402; called by muse, mutect2, varscan2
- KCNA7 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 85/761 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV55504041; called by muse, mutect2, varscan2
- KCNH7 | c.3248C>T p.P1083L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.307); catalogued as rs1319348402; called by muse, mutect2, varscan2
- KCNJ12 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs781983715, COSV59166412; called by muse, varscan2
- KCNS3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.248); catalogued as COSV58406530; called by muse, mutect2, varscan2
- KDR | c.3839C>T p.P1280L | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV55764028; called by muse, mutect2, varscan2
- KHK | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 127/764 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs1464530815; called by muse, mutect2, varscan2
- KIAA0408 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV64115887; called by muse, mutect2, varscan2
- KIAA1109 | c.358+1G>A p.X120_splice | Splice Site (SNP) | VAF 9/131 reads (7%) | catalogued as COSV99151074; called by muse, mutect2
- KIF1A | c.3379G>A p.G1127R | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395195328; called by muse, mutect2, varscan2
- KIF2C | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs772519336; called by muse, mutect2, varscan2
- KIFC2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as COSV56761780; called by muse, mutect2, varscan2
- KITLG | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.939); catalogued as rs759217048; called by muse, mutect2, varscan2
- KLC2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 55/433 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57581729; called by muse, mutect2, varscan2
- KLC4 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1023098785; called by muse, mutect2
- KLHDC7A | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV68770085; called by muse, mutect2, varscan2
- KLHDC7B | c.1303C>T p.P435S (on ENST00000395676; = p.P1076S on NM_138433.5) | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464621584; called by muse, mutect2, varscan2
- KLHL7 | c.1531G>A p.V511I (on ENST00000339077 / NM_001031710.3; = p.V463I on NM_018846.5) | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as rs1197975920; called by muse, mutect2, varscan2
- KLK2 | c.554C>G p.A185G | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs751806019; called by muse, varscan2
- KMT2A | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63292523; called by muse, mutect2, varscan2
- KMT2C | c.1289G>A p.W430* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100076359, COSV100077754; called by muse, mutect2
- KMT2D | c.12523C>T p.P4175S | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs766500530; called by muse, mutect2, varscan2
- KMT2E | c.5276C>T p.P1759L | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV57572675; called by muse, mutect2
- KRBA2 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs139656920, COSV58779059; called by muse, mutect2
- KRT23 | c.798+1G>A p.X266_splice | Splice Site (SNP) | VAF 33/138 reads (24%) | catalogued as COSV52929144; called by muse, mutect2, varscan2
- KRT6A | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 218/1079 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs759307145, COSV58106799; called by muse, mutect2, varscan2
- KRTAP10-1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 57/478 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs782163395; called by muse, mutect2, varscan2
- KRTAP27-1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765681661, COSV67000900, COSV67001054; called by muse, mutect2, varscan2
- KRTAP4-7 | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 143/667 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV66951930; called by muse, mutect2, varscan2
- KSR1 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 58/250 reads (23%) | catalogued as COSV99261147; called by muse, mutect2, varscan2
- LACRT | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.205); catalogued as rs763824465, COSV57688909; called by muse, mutect2, varscan2
- LAMB2 | c.3607G>A p.D1203N | Missense Mutation (SNP) | VAF 104/507 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs1489480937; called by muse, mutect2, varscan2
- LAMB4 | c.192G>A p.E64= | Splice Region (SNP) | VAF 18/132 reads (14%) | catalogued as rs778358316; called by muse, mutect2, varscan2
- LAMP5 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1338590371, COSV55717163; called by muse, mutect2
- LAMTOR3 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1448741915; called by muse, mutect2, varscan2
- LANCL1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs764020159; called by muse, mutect2, varscan2
- LARGE1 | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 49/360 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as rs779725828; called by muse, mutect2, varscan2
- LATS1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.027); catalogued as COSV53589183; called by muse, mutect2, varscan2
- LCMT2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as rs142722274; called by muse, mutect2, varscan2
- LCT | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.26); catalogued as rs771272642; called by muse, varscan2
- LGALS12 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55369713; called by muse, mutect2
- LGALS16 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 77/360 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs764476165; called by muse, mutect2, varscan2
- LGR5 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.104); catalogued as COSV57002021, COSV57004906; called by muse, mutect2, varscan2
- LHFPL6 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65449948; called by muse, mutect2, varscan2
- LILRA6 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 144/1272 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54435860; called by muse, varscan2
- LLGL1 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 64/514 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1226054204; called by muse, mutect2, varscan2
- LOXHD1 | c.4076C>T p.A1359V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1384253106; called by muse, mutect2, varscan2
- LOXL2 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 59/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101207766; called by muse, mutect2, varscan2
- LPIN2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 98/499 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55241315; called by muse, mutect2, varscan2
- LRP2 | c.13840C>T p.P4614S | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1222400860, COSV99787037; called by muse, mutect2, varscan2
- LRP3 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as rs759881791, COSV53503172; called by muse, mutect2, varscan2
- LRP4 | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as rs776547887; called by muse, varscan2
- LRP8 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60099258; called by muse, mutect2
- LRRC17 | c.-141+1G>A | Splice Site (SNP) | VAF 64/371 reads (17%) | catalogued as rs759963809; called by muse, mutect2, varscan2
- LRRC29 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs376894911; called by muse, mutect2, varscan2
- LRRC37A3 | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 94/1990 reads (5%) | catalogued as rs1244044234; called by muse, mutect2
- LRRC4 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.292); catalogued as rs1412590926; called by muse, mutect2, varscan2
- LRRC45 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.249); catalogued as rs1321640720; called by muse, mutect2, varscan2
- LRRC4C | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53430803; called by muse, mutect2, varscan2
- LRRK2 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1259652933; called by muse, mutect2, varscan2
- LRRN3 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs771295780; called by muse, mutect2, varscan2
- LSS | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as rs763440644; called by muse, mutect2, varscan2
- LTK | c.1488G>A p.W496* | Nonsense Mutation (SNP) | VAF 37/330 reads (11%) | catalogued as rs770705285; called by muse, mutect2, varscan2
- LYPD2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs1230443006; called by muse, mutect2, varscan2
- LYST | c.4589G>A p.R1530K | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV67712985; called by muse, mutect2, varscan2
- MACF1 | c.6433G>A p.E2145K | Missense Mutation (SNP) | VAF 39/150 reads (26%) | catalogued as rs1168393704; called by muse, mutect2, varscan2
- MACF1 | c.9164C>T p.P3055L | Missense Mutation (SNP) | VAF 56/217 reads (26%) | catalogued as rs1456618937, COSV99246167; called by muse, mutect2, varscan2
- MAGI1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs774969090, COSV58334559; called by muse, mutect2, varscan2
- MAP11 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 90/417 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1164149409; called by muse, mutect2, varscan2
- MAP1S | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 90/493 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV60724999; called by muse, mutect2, varscan2
- MAP2K3 | c.212G>A p.G71D (on ENST00000342679 / NM_145109.3; = p.G42D on NM_002756.4) | Missense Mutation (SNP) | VAF 57/457 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752806793; called by muse, varscan2
- MAP7 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1473859887; called by muse, mutect2, varscan2
- MAPK12 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1300419273; called by muse, mutect2
- MAPK14 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 114/491 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100004786; called by muse, mutect2, varscan2
- MARCHF2 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 33/404 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53104084; called by muse, mutect2
- MAST3 | c.3913C>T p.P1305S | Missense Mutation (SNP) | VAF 76/606 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs777636124; called by muse, varscan2
- MATN2 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1270204309; called by muse, mutect2, varscan2
- MBOAT1 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as rs770256909; called by muse, mutect2, varscan2
- MBTPS1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV58571117; called by muse, mutect2
- MCAM | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV99875709; called by muse, mutect2, varscan2
- MCM3AP | c.4300G>A p.G1434S | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250976825; called by muse, mutect2
- MCM6 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs1329164092; called by muse, mutect2, varscan2
- MCOLN1 | c.1134G>A p.K378= | Splice Region (SNP) | VAF 133/611 reads (22%) | catalogued as rs202000556, COSV51180607; called by muse, mutect2, varscan2
- MED13L | c.2728C>T p.L910F | Missense Mutation (SNP) | VAF 22/565 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1336893095; called by muse, mutect2
- MED23 | c.2084C>T p.T695I | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as rs113634905; called by muse, mutect2, varscan2
- MEN1 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as CM021287, COSV53642987, COSV53646656; called by muse, mutect2, varscan2
- MEX3D | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1168128137; called by muse, mutect2
- MFSD12 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV100281371; called by muse, mutect2
- MGA | c.5017G>A p.V1673I | Missense Mutation (SNP) | VAF 104/463 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1387971639; called by muse, varscan2
- MGA | c.5647G>A p.A1883T (on ENST00000219905 / NM_001164273.1; = p.A1674T on NM_001080541.2) | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs370050031; called by muse, mutect2, varscan2
- MGLL | c.629G>A p.G210D (on ENST00000398104 / NM_001003794.2; = p.G220D on NM_007283.6) | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV99412518; called by muse, mutect2
- MICAL2 | c.4856C>T p.P1619L | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as rs1372430786; called by muse, mutect2, varscan2
- MIER2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV53397581; called by muse, varscan2
- MINAR1 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV59584731; called by muse, mutect2
- MINDY2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV57507081; called by muse, mutect2
- MINDY4 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.054); catalogued as rs201132541; called by muse, mutect2, varscan2
- MIOX | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs769242335, COSV53312893; called by muse, mutect2, varscan2
- MKI67 | c.8197G>A p.V2733I | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.581); catalogued as COSV64076582; called by muse, mutect2
- MLANA | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101199968; called by muse, mutect2, varscan2
- MMD2 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.466); catalogued as rs1318481797; called by muse, mutect2, varscan2
- MMRN1 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 45/226 reads (20%) | catalogued as rs1285256374; called by muse, mutect2
- MN1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.116); catalogued as rs1251099459; called by mutect2, varscan2
- MPST | c.733G>A p.V245M (on ENST00000341116 / NM_001369904.2; = p.V265M on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/520 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as rs762471056; called by muse, mutect2, varscan2
- MRGPRE | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.331); catalogued as rs764661225; called by muse, mutect2, varscan2
- MRNIP | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs777834009; called by muse, mutect2, varscan2
- MROH1 | c.4865C>T p.P1622L | Missense Mutation (SNP) | VAF 102/545 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs992300324; called by muse, mutect2, varscan2
- MSH4 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 40/176 reads (23%) | catalogued as COSV54200448; called by muse, mutect2, varscan2
- MSH6 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 134/637 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as rs758432113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSL2 | c.1117A>G p.T373A | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.027); catalogued as rs569470420; called by muse, mutect2
- MST1R | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 53/510 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs763045729, COSV56569039; called by muse, mutect2, varscan2
- MSX2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs781619692, COSV53326649; called by muse, mutect2, varscan2
- MTHFSD | c.373C>T p.P125S (on ENST00000360900 / NM_001159377.2; = p.P124S on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59804700; called by muse, mutect2, varscan2
- MTMR11 | c.1306C>T p.L436F (on ENST00000439741 / NM_001145862.2; = p.L364F on NM_181873.3) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54967001; called by muse, mutect2
- MTMR8 | c.2081G>A p.S694N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs778850947, COSV66392160; called by muse, mutect2, varscan2
- MTUS1 | c.3472G>A p.D1158N (on ENST00000262102 / NM_001363061.1; = p.D324N on NM_020749.4) | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50555028; called by muse, mutect2, varscan2
- MUC16 | c.41680C>T p.P13894S | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.992); catalogued as rs953854315; called by muse, mutect2, varscan2
- MUC16 | c.16177C>T p.P5393S | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV67448841; called by muse, mutect2, varscan2
- MUC16 | c.5513C>T p.A1838V | Missense Mutation (SNP) | VAF 57/297 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs752594278; called by muse, mutect2, varscan2
- MUC4 | c.12884C>T p.P4295L (on ENST00000463781 / NM_018406.7; = p.P59L on NM_004532.6) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs931743314; called by muse, mutect2, varscan2
- MUC4 | c.5435C>T p.T1812I | Missense Mutation (SNP) | VAF 33/744 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); catalogued as rs778219820; called by muse, mutect2
- MYBL2 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs766524660; called by muse, mutect2, varscan2
- MYCN | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1371290338; called by muse, mutect2, varscan2
- MYH13 | c.4084C>T p.Q1362* | Nonsense Mutation (SNP) | VAF 117/507 reads (23%) | catalogued as rs199890413; called by muse, mutect2, varscan2
- MYH6 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 94/576 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100676302; called by muse, varscan2
- MYLK2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 60/349 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV65659898; called by muse, mutect2, varscan2
- MYO15A | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV52752101; called by muse, mutect2, varscan2
- MYO15A | c.9951C>T p.V3317= | Splice Region (SNP) | VAF 105/593 reads (18%) | catalogued as rs780864387; called by muse, mutect2, varscan2
- MYO18B | c.2827G>A p.V943M | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs999615024; called by muse, mutect2
- MYO5B | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 82/543 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs777222341; called by muse, mutect2, varscan2
- MYOCD | c.591+1G>A p.X197_splice | Splice Site (SNP) | VAF 18/127 reads (14%) | catalogued as COSV100590864; called by muse, mutect2, varscan2
- MYOM1 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.169); catalogued as COSV55297028; called by muse, mutect2
- MYT1 | c.2081G>A p.G694D | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as rs756892784; called by muse, mutect2, varscan2
- NAPSA | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364607909; called by muse, mutect2, varscan2
- NAPSA | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776944945; called by muse, varscan2
- NARF | c.1129+1G>A p.X377_splice | Splice Site (SNP) | VAF 22/119 reads (18%) | catalogued as rs767522810; called by muse, mutect2, varscan2
- NAV2 | c.2957G>A p.R986Q (on ENST00000396087 / NM_001244963.2; = p.R963Q on NM_145117.5) | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs752704652; called by muse, varscan2
- NAV3 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1174362847; called by muse, mutect2, varscan2
- NBEAL1 | c.4204G>A p.E1402K | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV71374086; called by muse, mutect2, varscan2
- NBPF12 | c.3484C>T p.L1162F | Missense Mutation (SNP) | VAF 34/909 reads (4%) | SIFT tolerated (0.73); catalogued as COSV58770132; called by muse, mutect2
- NBPF9 | c.2663C>T p.S888L | Missense Mutation (SNP) | VAF 154/728 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs79474112; called by muse, mutect2, varscan2
- NCAPD2 | c.3538G>A p.G1180R | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1472426192; called by muse, mutect2, varscan2
- NCOR1 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 49/285 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); catalogued as COSV51985817, COSV51989049; called by muse, mutect2, varscan2
- NDNF | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.871); catalogued as rs781717177, COSV65633451; called by muse, mutect2, varscan2
- NDUFS2 | c.1116+1G>A p.X372_splice | Splice Site (SNP) | VAF 62/333 reads (19%) | catalogued as rs1459618345; called by muse, mutect2, varscan2
- NEB | c.18589G>A p.D6197N | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1364424120; called by muse, varscan2
- NECTIN3 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV60551292, COSV60552039; called by muse, mutect2, varscan2
- NEFM | c.2236G>A p.V746M | Missense Mutation (SNP) | VAF 115/528 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs890611466; called by muse, mutect2, varscan2
- NEK5 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769520527; called by muse, mutect2, varscan2
- NEO1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV56066984; called by muse, mutect2, varscan2
- NEO1 | c.4250C>T p.P1417L | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369017263; called by muse, mutect2, varscan2
- NES | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs765528071, COSV63961646; called by muse, mutect2, varscan2
- NEURL3 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 51/462 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1558598143, COSV100182432; called by muse, mutect2, varscan2
- NF1 | c.60+1G>A p.X20_splice | Splice Site (SNP) | VAF 68/280 reads (24%) | catalogued as CD147189, CS076633, COSV62199447; called by muse, varscan2
- NF1 | c.6686G>A p.W2229* (on ENST00000358273 / NM_001042492.3; = p.W2208* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 60/375 reads (16%) | catalogued as CM143464; called by muse, mutect2, varscan2
- NFKBID | c.7G>A p.A3T (on ENST00000396901; = p.A155T on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs775054726; called by muse, mutect2, varscan2
- NFYC | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.457); catalogued as rs1418852224; called by muse, mutect2, varscan2
- NHLH1 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 120/550 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57483744; called by muse, mutect2, varscan2
- NLRP14 | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55063778; called by muse, mutect2, varscan2
- NLRP5 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); catalogued as rs760289445; called by muse, mutect2, varscan2
- NME1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 161/677 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV50148136; called by muse, mutect2, varscan2
- NOG | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs1039686376; called by muse, mutect2, varscan2
- NOM1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867052047; called by muse, mutect2
- NOM1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 66/451 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1390308081; called by muse, mutect2, varscan2
- NOM1 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 109/448 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51981585; called by muse, mutect2, varscan2
- NOXO1 | c.825G>A p.W275* (on ENST00000397280 / NM_172168.3; = p.W269* on NM_144603.4) | Nonsense Mutation (SNP) | VAF 29/736 reads (4%) | catalogued as rs1372148582; called by muse, mutect2
- NPAP1 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1484594194, COSV61504140; called by muse, mutect2, varscan2
- NPAS1 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs1243196097; called by muse, mutect2, varscan2
- NPC1L1 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs776788939; called by muse, mutect2
- NPNT | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs551106994; called by muse, mutect2, varscan2
- NPRL3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.899); catalogued as rs745987603; called by muse, mutect2, varscan2
- NR2E3 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs754661615; called by muse, mutect2, varscan2
- NRCAM | c.2788G>A p.V930M (on ENST00000379028 / NM_001371124.1; = p.V914M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/626 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1480606027; called by muse, mutect2, varscan2
- NRG2 | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1242667168; called by muse, mutect2, varscan2
- NRSN2 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV66526854; called by muse, mutect2, varscan2
- NRXN1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 90/462 reads (19%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.517); catalogued as COSV68046776; called by muse, varscan2
- NTN4 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.099); catalogued as rs201957399; called by muse, mutect2, varscan2
- NTRK2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 34/573 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV52876588; called by muse, mutect2
- NUFIP1 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs144069108; called by muse, mutect2, varscan2
- NUTM2B | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 194/1677 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as rs1418310060; called by muse, mutect2, varscan2
- NVL | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV55873370, COSV55875653; called by muse, mutect2
- NWD1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.637); catalogued as rs867793000; called by muse, mutect2, varscan2
- NYAP1 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs1371451867; called by muse, mutect2, varscan2
- OBI1 | c.300+1G>A p.X100_splice | Splice Site (SNP) | VAF 18/121 reads (15%) | catalogued as rs1418544333; called by muse, mutect2, varscan2
- OCA2 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 24/547 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.327); catalogued as rs868535053; called by muse, mutect2
- OCEL1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.751); catalogued as rs769947475; called by mutect2, varscan2
- OPLAH | c.1919G>A p.G640D | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV70677107; called by muse, mutect2, varscan2
- OR1M1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 52/568 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1568297320, COSV70037481; called by muse, mutect2
- OR2K2 | c.398C>T p.S133F (on ENST00000374428; = p.S104F on NM_205859.2) | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV57018519; called by muse, mutect2, varscan2
- OR4D11 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV57585596; called by muse, mutect2, varscan2
- OR52L1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV59989072; called by muse, mutect2, varscan2
- OR56B4 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 46/410 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs779511351, COSV57204826; called by muse, mutect2, varscan2
- OR5W2 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60614774, COSV60615520; called by muse, mutect2
- OR7A5 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as rs951017608; called by muse, mutect2, varscan2
- OSMR | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1208559994; called by muse, mutect2
- OXER1 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs749642199; called by muse, varscan2
- OXTR | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.024); catalogued as rs1199625461; called by muse, mutect2
- PAICS | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | PolyPhen benign (0.268); catalogued as rs1364600243; called by muse, mutect2, varscan2
- PAM | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1023910255; called by muse, mutect2, varscan2
- PARP4 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV67960781; called by muse, mutect2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 74/427 reads (17%) | catalogued as rs756801119; called by mutect2, varscan2
- PAX6 | c.142-8C>T | Splice Region (SNP) | VAF 103/474 reads (22%) | catalogued as rs886048203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PBRM1 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs758198630, COSV56311783; called by muse, mutect2, varscan2
- PBX3 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.014); catalogued as rs542398925; called by muse, varscan2
- PCCA | c.106-1G>A p.X36_splice | Splice Site (SNP) | VAF 42/318 reads (13%) | catalogued as rs769819121; called by muse, mutect2, varscan2
- PCDHA12 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 25/550 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); catalogued as COSV56534021; called by muse, mutect2
- PCDHA3 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 83/400 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs148196865, COSV63538858; called by muse, mutect2, varscan2
- PCDHB10 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 74/341 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782048683; called by muse, mutect2, varscan2
- PCDHB3 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 275/1063 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.823); catalogued as rs781988108; called by muse, mutect2, varscan2
- PCLO | c.13139C>T p.P4380L | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100440332; called by muse, mutect2, varscan2
- PCLO | c.8063G>A p.S2688N | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs1003433778; called by muse, mutect2, varscan2
- PCNX3 | c.3265G>A p.A1089T | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.037); catalogued as rs377764546; called by muse, varscan2
- PCSK1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 80/330 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.031); catalogued as COSV60736845; called by muse, mutect2, varscan2
- PCSK9 | c.1682-1G>A p.X561_splice | Splice Site (SNP) | VAF 27/194 reads (14%) | catalogued as COSV99598899; called by muse, mutect2, varscan2
- PDCD11 | c.3224G>A p.G1075D | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100874427; called by muse, mutect2, varscan2
- PDCD11 | c.4120G>A p.G1374R | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100874387; called by muse, mutect2, varscan2
- PDE1B | c.1267+1G>A p.X423_splice | Splice Site (SNP) | VAF 12/220 reads (5%) | catalogued as COSV54489651; called by muse, mutect2
- PDILT | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 72/366 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.575); catalogued as rs755098526; called by mutect2, varscan2
- PDK4 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV99138965; called by muse, mutect2
- PEX6 | c.2240G>A p.G747D | Missense Mutation (SNP) | VAF 75/500 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362080429; called by muse, mutect2, varscan2
- PFKL | c.639G>A p.G213= | Splice Region (SNP) | VAF 35/176 reads (20%) | catalogued as COSV100827315; called by muse, mutect2, varscan2
- PGAP6 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 20/341 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as rs1381529343; called by muse, mutect2
- PGGT1B | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56973672; called by muse, mutect2, varscan2
- PHACTR4 | c.209C>T p.S70F (on ENST00000373839 / NM_001350159.2; = p.S80F on NM_023923.4) | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65785060; called by muse, mutect2
- PHF6 | c.241-1G>A p.X81_splice | Splice Site (SNP) | VAF 12/114 reads (11%) | catalogued as COSV59704473; called by muse, mutect2
- PID1 | c.554G>A p.R185K (on ENST00000354069 / NM_001330156.1; = p.R183K on NM_017933.5) | Missense Mutation (SNP) | VAF 123/545 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs868845353, COSV62484078; called by muse, mutect2, varscan2
- PIEZO2 | c.7597dup p.S2533Ffs*20 | Frame Shift Ins (INS) | VAF 15/137 reads (11%) | catalogued as rs1451012640; called by mutect2, pindel
- PIGG | c.1595G>A p.G532D (on ENST00000453061 / NM_001127178.3; = p.G524D on NM_017733.4) | Missense Mutation (SNP) | VAF 125/617 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs753841067; called by muse, mutect2, varscan2
- PIGM | c.851G>A p.S284N | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs374754962; called by muse, mutect2, varscan2
- PINK1 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 113/479 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58631903; called by muse, mutect2, varscan2
- PITPNM1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs776940244, COSV62709727; called by muse, mutect2, varscan2
- PIWIL1 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as COSV55346593; called by muse, mutect2, varscan2
- PIWIL3 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.877); catalogued as rs187027471, COSV59995336; called by muse, mutect2, varscan2
- PKD1L2 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs1193565770, COSV61420486; called by muse, varscan2
- PKD2L2 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV51801480; called by muse, mutect2, varscan2
- PKLR | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 99/536 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs370316462, CM950962; called by muse, mutect2, varscan2
- PKP2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 94/528 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as CM1313303; called by muse, mutect2, varscan2
- PLA2G6 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.686); catalogued as rs1407292338; called by muse, mutect2, varscan2
- PLBD2 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.154); catalogued as COSV55106252; called by muse, varscan2
- PLCH2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as rs1281461797; called by muse, mutect2, varscan2
- PLEC | c.13502C>T p.T4501I (on ENST00000322810 / NM_201380.4; = p.T4391I on NM_000445.5) | Missense Mutation (SNP) | VAF 17/364 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs1208514926; called by muse, mutect2
- PLEKHG3 | c.1796G>A p.G599D (on ENST00000394691; = p.G655D on NM_001308147.2) | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs1566717103, COSV55978552; called by muse, mutect2, varscan2
- PLEKHH3 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99511667; called by muse, mutect2, varscan2
- PLEKHM3 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 60/418 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs753980442; called by muse, mutect2, varscan2
- PLK1 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs758643617; called by muse, mutect2, varscan2
- PLXNA3 | c.4538C>T p.T1513I | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs1259860516, COSV63754762; called by muse, mutect2
- PNLIPRP3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs373999631; called by muse, mutect2, varscan2
- PNMA2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.14); catalogued as rs1213678518; called by muse, mutect2, varscan2
- PNPLA2 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1246963580; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57965521; called by muse, mutect2, varscan2
- POLE | c.2986G>A p.G996S | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1216797884, COSV57693145; called by muse, mutect2
- POSTN | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101123378, COSV65713570; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs768050754; called by muse, mutect2, varscan2
- PPIL6 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354923545; called by muse, mutect2, varscan2
- PPM1D | c.1535dup p.N512Kfs*16 | Frame Shift Ins (INS) | VAF 40/357 reads (11%) | catalogued as rs763475304; called by mutect2, varscan2
- PPP1CC | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100534802; called by muse, mutect2, varscan2
- PPP1R3A | c.1628G>A p.R543K | Missense Mutation (SNP) | VAF 45/422 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.3); catalogued as COSV52880421; called by muse, mutect2, varscan2
- PRKDC | c.4160G>A p.G1387E | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV58054615; called by muse, mutect2, varscan2
- PRM3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as rs1284035953; called by muse, mutect2, varscan2
- PRMT5 | c.110+6G>A | Splice Region (SNP) | VAF 18/154 reads (12%) | catalogued as rs199765768; called by muse, mutect2, varscan2
- PRODH2 | c.1603C>T p.P535S (on ENST00000301175; = p.P459S on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV56561254; called by muse, mutect2
- PROSER1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61490016; called by muse, mutect2, varscan2
- PRPF31 | c.1073+6G>A | Splice Region (SNP) | VAF 71/348 reads (20%) | catalogued as rs765404848; called by muse, mutect2, varscan2
- PRR22 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs759158049; called by mutect2, varscan2
- PRR30 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745586182; called by muse, mutect2, varscan2
- PRRT3 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV55976208; called by muse, mutect2, varscan2
- PRRX1 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as rs1406921492; called by muse, mutect2
- PRSS38 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750175996; called by muse, mutect2, varscan2
- PSAPL1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59842535; called by muse, mutect2, varscan2
- PSMD2 | c.1539G>A p.E513= | Splice Region (SNP) | VAF 51/171 reads (30%) | catalogued as rs747748170; called by muse, mutect2, varscan2
- PSME4 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as rs934272409, COSV66362998; called by muse, mutect2, varscan2
- PSRC1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 41/395 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs372061380; called by muse, mutect2, varscan2
- PTBP3 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 25/129 reads (19%) | catalogued as COSV52958390; called by muse, mutect2, varscan2
- PTEN | c.164+1G>A p.X55_splice | Splice Site (SNP) | VAF 14/158 reads (9%) | catalogued as CD043800, CS013829, CS132270, CS147226, COSV64291461, COSV64302445, COSV64308544; called by muse, mutect2
- PTGER2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.227); catalogued as rs1265519374; called by muse, mutect2, varscan2
- PTGIS | c.378G>A p.L126= | Splice Region (SNP) | VAF 18/348 reads (5%) | catalogued as rs967489527; called by muse, mutect2
- PTPN13 | c.3239G>A p.R1080K (on ENST00000411767 / NM_080683.3; = p.R1061K on NM_006264.3) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV57412983; called by muse, mutect2
- PTPRQ | c.3415C>T p.R1139C (on ENST00000616559; = p.R1097C on NM_001145026.2) | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs951616671; called by muse, mutect2, varscan2
- QARS1 | c.1896G>A p.W632* | Nonsense Mutation (SNP) | VAF 41/192 reads (21%) | catalogued as rs753463624; called by muse, mutect2, varscan2
- RAG1 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 83/378 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100200638; called by muse, mutect2, varscan2
- RANBP2 | c.3851G>A p.R1284K | Missense Mutation (SNP) | VAF 195/794 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV99311918; called by muse, mutect2, varscan2
- RANBP2 | c.6187C>T p.L2063F | Missense Mutation (SNP) | VAF 25/817 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51706106; called by muse, mutect2
- RAPGEF6 | c.3944G>A p.G1315E | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.045); catalogued as rs759377013; called by muse, mutect2, varscan2
- RAPGEFL1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.988); catalogued as rs1334000386; called by muse, mutect2, varscan2
- RARS2 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101057011; called by muse, mutect2, varscan2
- RASGRF1 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV69183366; called by muse, mutect2
- RASIP1 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.283); catalogued as rs1292118325; called by muse, mutect2
- RB1 | c.1850G>A p.G617D | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as CD942048; called by muse, mutect2
- RBP3 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs1555211388; called by muse, mutect2, varscan2
- RCN1 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs1023202519; called by muse, mutect2, varscan2
- RECQL4 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 18/393 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.049); catalogued as rs1319378486; called by muse, mutect2
- RECQL5 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV53126926; called by muse, mutect2, varscan2
- RELN | c.9357G>A p.M3119I | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.854); catalogued as COSV59009100; called by muse, mutect2, varscan2
- REPIN1 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 78/490 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1226249166; called by muse, mutect2, varscan2
- RETREG3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as rs765041342, COSV58703974; called by muse, mutect2, varscan2
- RGL1 | c.1594C>T p.P532S (on ENST00000360851 / NM_001297672.2; = p.P567S on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745474593; called by muse, mutect2, varscan2
- RGS7BP | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as rs773845244; called by muse, mutect2, varscan2
- RGS9 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 114/574 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771246224; called by muse, mutect2, varscan2
- RHBDD2 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as rs1554544484, COSV99138189; called by muse, mutect2, varscan2
- RNASEH1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1266318997; called by muse, mutect2, varscan2
- RNF38 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52392785; called by muse, mutect2
- ROS1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV100876254; called by muse, mutect2
- RP1L1 | c.1928G>A p.S643N | Missense Mutation (SNP) | VAF 75/558 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV66760988; called by muse, mutect2, varscan2
- RP9 | c.313+3G>A | Splice Region (SNP) | VAF 66/602 reads (11%) | catalogued as rs1187117825; called by muse, mutect2, varscan2
- RPN2 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 143/655 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as rs1279812710, COSV52909239; called by muse, mutect2, varscan2
- RPS6KC1 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344616472; called by muse, mutect2
- RRP1 | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1353492753; called by muse, mutect2
- RRP9 | c.390+1G>A p.X130_splice | Splice Site (SNP) | VAF 75/325 reads (23%) | catalogued as rs1199338128; called by muse, mutect2, varscan2
- RSC1A1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs748304784; called by muse, mutect2, varscan2
- RSPRY1 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768294786, COSV68028547; called by muse, mutect2, varscan2
- RTF1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV101048025; called by muse, mutect2, varscan2
- RTN4 | c.3337G>A p.D1113N (on ENST00000337526 / NM_020532.5; = p.D120N on NM_007008.3) | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58274126; called by muse, mutect2, varscan2
- RUNX2 | c.1325C>T p.T442I (on ENST00000371438; = p.T420I on NM_001015051.3) | Missense Mutation (SNP) | VAF 199/906 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61844686; called by muse, mutect2, varscan2
- RUSF1 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs753411992; called by muse, mutect2, varscan2
- SAFB | c.1197G>A p.K399= | Splice Region (SNP) | VAF 24/238 reads (10%) | catalogued as rs763805843, COSV99412419; called by muse, mutect2, varscan2
- SAMD9L | c.3644C>T p.P1215L | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1224907650, COSV59081587; called by muse, mutect2
- SAMHD1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV99483707; called by muse, mutect2, varscan2
- SBNO2 | c.3833C>T p.A1278V | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.019); catalogued as rs1302123719; called by muse, mutect2, varscan2
- SCARF2 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 48/1061 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422086152, COSV56732198; called by muse, mutect2
- SCFD2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1252909584; called by muse, mutect2, varscan2
- SCG2 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs1246124133, COSV59540947; called by muse, mutect2, varscan2
- SCMH1 | c.854C>T p.P285L (on ENST00000326197 / NM_001031694.2; = p.P238L on NM_012236.4) | Missense Mutation (SNP) | VAF 105/533 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as COSV100401732; called by muse, mutect2, varscan2
- SCN1A | c.3626G>A p.R1209K (on ENST00000303395 / NM_001202435.3; = p.R1198K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/361 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57690903; called by muse, mutect2, varscan2
- SCN3A | c.910A>G p.T304A | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV51809191; called by muse, mutect2, varscan2
- SCN9A | c.4892G>A p.R1631H (on ENST00000303354; = p.R1620H on NM_002977.3) | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs201079869; called by muse, mutect2, varscan2
- SCN9A | c.2075G>A p.R692K (on ENST00000303354; = p.R681K on NM_002977.3) | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.127); catalogued as COSV100311075, COSV57608693; called by muse, mutect2, varscan2
- SCNN1G | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs147276737; called by muse, mutect2, varscan2
- SCTR | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV99191661; called by muse, mutect2, varscan2
- SDK2 | c.5861G>A p.R1954Q | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.383); catalogued as rs373850295; called by muse, mutect2, varscan2
- SEC16A | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.486); catalogued as rs1441239230; called by muse, mutect2, varscan2
- SELENON | c.537G>A p.G179= | Splice Region (SNP) | VAF 22/438 reads (5%) | catalogued as rs1341387676, COSV100823481; called by muse, mutect2
- SEMA3F | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1364572533; called by muse, mutect2
- SENP7 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.122); catalogued as rs1211614195; called by muse, mutect2
- SEPTIN8 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51523690; called by muse, mutect2
- SERPING1 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 85/379 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as rs751126649; called by muse, mutect2, varscan2
- SETX | c.7426C>T p.P2476S | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1564464373; called by muse, mutect2, varscan2
- SFXN1 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs1402897684, COSV58494563; called by muse, mutect2, varscan2
- SGK2 | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs779076570; called by muse, mutect2, varscan2
- SGPP1 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 82/426 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs536293796; called by muse, varscan2
- SHANK2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 69/555 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs548275131; called by muse, mutect2, varscan2
- SHB | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100891084; called by muse, mutect2, varscan2
- SHMT1 | c.243-1G>A p.X81_splice | Splice Site (SNP) | VAF 201/811 reads (25%) | catalogued as rs1473316029; called by muse, mutect2, varscan2
- SHPRH | c.3154C>T p.R1052C (on ENST00000275233 / NM_001042683.3; = p.R1061C on NM_173082.3) | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749619791, COSV51606814; called by muse, mutect2, varscan2
- SHROOM1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1476188689, COSV60581135; called by muse, mutect2, varscan2
- SIGLEC1 | c.3349C>T p.L1117F | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1333531691; called by muse, mutect2, varscan2
- SIK3 | c.3302C>T p.P1101L (on ENST00000445177 / NM_001366686.2; = p.P1059L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99407187; called by muse, mutect2, varscan2
- SIPA1L3 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1204400975, COSV99728084; called by muse, mutect2, varscan2
- SLC12A3 | c.2632G>A p.A878T (on ENST00000563236 / NM_001126108.2; = p.A887T on NM_000339.3) | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.254); catalogued as COSV52639813; called by muse, mutect2, varscan2
- SLC24A1 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 128/496 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs892193699; called by muse, mutect2, varscan2
- SLC26A5 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 60/450 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as rs1352257966; called by muse, mutect2, varscan2
- SLC27A4 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 21/454 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.643); catalogued as rs1375260725; called by muse, mutect2
- SLC35F1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.648); catalogued as rs935520327; called by muse, mutect2, varscan2
- SLC46A1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 33/815 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551213215; called by muse, mutect2
- SLC6A3 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 147/692 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1338596075; called by muse, mutect2, varscan2
- SLCO1B1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV57012370, COSV57016415; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866G>A p.G622= (on ENST00000540229 / NM_001371097.1; = p.R561= on NM_001009562.4) | Splice Region (SNP) | VAF 12/95 reads (13%) | catalogued as rs768961254; called by mutect2, varscan2
- SLCO4C1 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as COSV60518967; called by muse, mutect2, varscan2
- SLF2 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs557575122; called by muse, mutect2
- SLFNL1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1316277521; called by muse, mutect2
- SLIT1 | c.4547C>T p.T1516I | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs528749604; called by muse, mutect2, varscan2
- SLITRK3 | c.2669C>T p.P890L | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1560052493; called by muse, mutect2
- SLMAP | c.1147G>A p.V383I (on ENST00000428312 / NM_001377924.1; = p.V404I on NM_007159.5) | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs751946618; called by muse, mutect2, varscan2
- SMARCA2 | c.3605G>A p.G1202D | Missense Mutation (SNP) | VAF 69/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61810907; called by muse, mutect2, varscan2
- SMC6 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as rs1294248729; called by muse, mutect2, varscan2
- SMCHD1 | c.2729G>A p.G910D | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs868405096, COSV55264562; called by muse, mutect2, varscan2
- SMCR8 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58175611; called by muse, mutect2, varscan2
- SMG7 | c.3395C>T p.T1132I | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs1259293600; called by muse, mutect2, varscan2
- SMPD3 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as rs775387559, COSV54710984; called by muse, mutect2, varscan2
- SNAPC4 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747868175; called by muse, mutect2, varscan2
- SNRPN | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV57600732; called by muse, mutect2
3,704 further variants in this file (1,858 protein-altering or splice-affecting, 1,237 silent, 609 other) are not listed here.
